Gene-level copy-number profile of tumor specimen MP2PRT-PAVEJH-TMP1-A from MP2PRT case MP2PRT-PAVEJH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,169 days).
Specimen MP2PRT-PAVEJH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7d69a469-d9e6-4681-b329-900e148c0515.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVEJH-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/c0694acb-e765-4b11-9d71-161075cf4f2a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 894; copy number 2: 39,507; copy number 3: 1,330; copy number 4: 8,643; copy number 5: 3,008; copy number 6: 3,516; copy number 7: 1,304; copy number 8: 141.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 38 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,345 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:179,099,330–179,229,684, 1 gene, copy number 5 (within-gene range 4–5): ABL2.
- chr1:179,183,734–179,554,735, 11 genes, copy number 5 (within-gene range 4–5): SETP10, AL512326.2, AL512326.1, EIF4A1P11, AL512326.3, COX5BP8, AL512326.4, SOAT1, AXDND1, MEF2AP1, HNRNPA1P54.
- chr4:49,096–49,246,915, 706 genes, copy number 6–8 (broad region; genes not listed).
- chr4:51,843,000–190,092,279, 1,849 genes, copy number 6–7 (broad region; genes not listed).
- chr6:17,092,714–18,368,644, 25 genes, copy number 5: AL138740.1, STMND1, AL136305.1, RBM24, AL034372.1, CAP2, RPL7P26, SUMO2P13, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9.
- chr6:34,189,780–39,934,551, 142 genes, copy number 5 (broad region; genes not listed).
- chr6:41,789,896–41,895,361, 1 gene, copy number 5 (within-gene range 4–5): USP49.
- chr6:41,832,854–43,706,751, 76 genes, copy number 5 (broad region; genes not listed).
- chr10:14,061–38,466,176, 637 genes, copy number 5–6 (broad region; genes not listed).
- chr10:38,617,255–94,873,129, 937 genes, copy number 5–7 (broad region; genes not listed).
- chr10:109,184,934–133,778,699, 405 genes, copy number 6 (broad region; genes not listed).
- chr17:142,789–4,187,310, 166 genes, copy number 5 (broad region; genes not listed).
- chr17:34,980,512–49,476,988, 756 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:56,791,913–83,240,804, 871 genes, copy number 5 (broad region; genes not listed).
- chr18:3,411,608–3,478,978, 3 genes, copy number 5: TGIF1, BOD1P1, GAPLINC.
- chr18:20,946,906–22,228,029, 37 genes, copy number 5: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2.
- chr21:13,038,160–46,691,226, 722 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 894. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
